Somatic mutation profile of tumor specimen 0DAWAU from CCDI case PBBKPA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Myxopapillary ependymoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 13.3 years (4,856 days).
Specimen 0DAWAU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11772c29-2488-45cd-8691-2522ef5648db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAWAF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6cd96a7c-a1e2-4cdb-86f1-fca872ac7a83

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1, RNA 1, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRIA2 | c.1838C>T p.S613L | Missense Mutation (SNP) | VAF 35/328 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as COSV52381735; called by muse, mutect2, varscan2
- SH2D5 | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 19/255 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs764532491; called by muse, mutect2
- MARCOL | c.302T>C p.I101T | Missense Mutation (SNP) | VAF 52/680 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.027); called by muse, mutect2
- NSUN3 | c.370G>C p.V124L | Missense Mutation (SNP) | VAF 18/432 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZCCHC24 | c.642C>T p.D214= | Silent (SNP) | VAF 93/226 reads (41%) | catalogued as rs778777022; called by muse, mutect2, varscan2
- CASTOR3 | n.230T>A | RNA (SNP) | VAF 33/233 reads (14%) | called by muse, mutect2, varscan2
- TFPI | c.628+5333G>T | Intron (SNP) | VAF 36/308 reads (12%) | catalogued as COSV51902256; called by muse, mutect2
- ZNF730 | c.-14C>A | 5'UTR (SNP) | VAF 38/286 reads (13%) | called by muse, mutect2, varscan2
